Somatic mutation profile of tumor specimen TCGA-K4-A54R-01A (aliquot TCGA-K4-A54R-01A-11D-A26M-08) from TCGA case TCGA-K4-A54R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.1 years (21,601 days).
Specimen TCGA-K4-A54R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94c2cb29-2ffe-4d98-be9b-6769b1e49814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A54R-10A (Blood Derived Normal), aliquot TCGA-K4-A54R-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04b9912b-99f9-4402-9a67-05faca5a7d9a

The open-access MAF lists 1,064 somatic variants for this specimen: 773 protein-altering or splice-affecting, 261 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 663, Silent 261, Nonsense Mutation 82, Intron 13, Splice Site 12, 5'Flank 7, Frame Shift Del 6, Splice Region 6, 3'UTR 5, RNA 4, Frame Shift Ins 3, Translation Start Site 1.

Variants (750 of 1,064; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR1 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555769818, COSV62087306; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, varscan2
- ABCA4 | c.6788G>A p.R2263Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs281865407, CM015096, COSV64670587, COSV64674040; called by muse, mutect2, varscan2
- ABCA9 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.038); catalogued as COSV60619792; called by muse, mutect2, varscan2
- ABCC9 | c.4411A>T p.I1471F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV53961541; called by muse, mutect2, varscan2
- AC005324.2 | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV60885455; called by muse, mutect2, varscan2
- AC092718.8 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV100202808; called by muse, mutect2, varscan2
- ACAA2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1040574362, COSV53269815; called by muse, mutect2, varscan2
- ACCSL | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV66579821; called by muse, mutect2, varscan2
- ACSF3 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs755491777, COSV58076250; called by muse, mutect2, varscan2
- ACSF3 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217095212, COSV58076267; called by muse, mutect2, varscan2
- ACSM4 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756182664, COSV68066508; called by muse, mutect2, varscan2
- ACY3 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV54827946; called by muse, mutect2, varscan2
- ADAM10 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.241); catalogued as COSV53048927, COSV53049757; called by muse, mutect2, varscan2
- ADAM19 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV57422120; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1041024471, COSV52807626; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.926); catalogued as COSV65876668; called by muse, mutect2
- ADCK1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV99451374; called by muse, mutect2, varscan2
- ADCY8 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV53894881, COSV53907491, COSV53918807; called by muse, mutect2, varscan2
- ADGRB3 | c.557C>G p.T186R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs760945188, COSV65380561; called by muse, mutect2, varscan2
- ADGRG4 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV54948469; called by muse, mutect2, varscan2
- ADGRL1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61563447; called by muse, mutect2, varscan2
- ADGRV1 | c.16381G>A p.E5461K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs1210003878, COSV67981724; called by muse, mutect2, varscan2
- AEN | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60428744; called by muse, mutect2, varscan2
- AGAP3 | c.1510C>T p.Q504* (on ENST00000622464; = p.Q540* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV101257077; called by muse, mutect2, varscan2
- AGRN | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65067498; called by muse, mutect2, varscan2
- AGRP | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1414719119, COSV52096538; called by muse, mutect2, varscan2
- AHCTF1 | c.1363G>A p.E455K (on ENST00000366508; = p.E429K on NM_015446.5) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV58245351; called by muse, mutect2, varscan2
- AHNAK | c.9308C>A p.P3103H | Missense Mutation (SNP) | VAF 101/347 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57202316; called by muse, mutect2, varscan2
- AHNAK | c.7576G>A p.E2526K | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.969); catalogued as rs750483775, COSV57202331; called by muse, mutect2, varscan2
- AHNAK | c.4813G>T p.E1605* | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99946597; called by muse, mutect2, varscan2
- AHR | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV54121273; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2
- AIFM2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV57158490; called by muse, mutect2, varscan2
- AKAP9 | c.3599C>G p.S1200C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV100662192; called by muse, mutect2
- AL136295.1 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV55777737; called by muse, mutect2, varscan2
- AL645922.1 | c.2845G>C p.D949H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV54959029; called by muse, mutect2, varscan2
- ALDH1L2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV51552602; called by muse, mutect2, varscan2
- ALDH9A1 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV61338859; called by muse, mutect2, varscan2
- ALMS1 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as COSV52501451; called by muse, mutect2, varscan2
- ALPK3 | c.4369G>C p.E1457Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51928547, COSV51930935; called by muse, mutect2, varscan2
- AMMECR1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53315893; called by muse, mutect2, varscan2
- AMOT | c.2191G>A p.E731K (on ENST00000371959 / NM_001113490.1; = p.E322K on NM_133265.3) | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV59059919; called by muse, mutect2, varscan2
- AMPD3 | c.1807G>A p.A603T (on ENST00000396553 / NM_001025389.2; = p.A612T on NM_000480.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV67329757; called by muse, mutect2, varscan2
- ANAPC7 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV71443654; called by muse, mutect2, varscan2
- ANKFN1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1268403813, COSV59439805, COSV59447659; called by muse, mutect2, varscan2
- ANKRD42 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV52614131; called by muse, mutect2, varscan2
- ANKRD44 | c.2631G>A p.M877I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV56548603; called by muse, mutect2, varscan2
- ANO8 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs760029411, COSV50172846, COSV50175923; called by muse, mutect2, varscan2
- ANP32A | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as COSV51189296; called by muse, mutect2, varscan2
- AP1G1 | c.1969C>T p.L657F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs762724915, COSV55484667; called by muse, mutect2, varscan2
- AP1M2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs549899023, COSV51565339; called by muse, mutect2, varscan2
- AP3B1 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs780402652, COSV54875623; called by muse, mutect2, varscan2
- APAF1 | c.622C>T p.Q208* (on ENST00000551964 / NM_181861.2; = p.Q197* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV59662203; called by muse, mutect2, varscan2
- APP | c.469-1G>C p.X157_splice | Splice Site (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100695534; called by muse, mutect2, varscan2
- ARHGAP24 | c.1626G>A p.M542I (on ENST00000395184 / NM_001025616.3; = p.M449I on NM_031305.3) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51986370; called by muse, mutect2, varscan2
- ARHGAP39 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.602); catalogued as COSV52766495; called by muse, mutect2, varscan2
- ARID1A | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV61374989; called by muse, mutect2, varscan2
- ARID1A | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 38/176 reads (22%) | catalogued as COSV61387383, COSV61388492; called by muse, mutect2, varscan2
- ARID1A | c.4536G>C p.Q1512H | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV61370563, COSV61373089; called by muse, mutect2, varscan2
- ARSJ | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536507; called by muse, mutect2, varscan2
- ASB15 | c.1208G>C p.G403A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51923447; called by muse, mutect2, varscan2
- ASTL | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100668306, COSV100668317; called by muse, mutect2, varscan2
- ATAD2 | c.3717G>C p.L1239F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54876774; called by muse, mutect2, varscan2
- ATAD2B | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53194630; called by muse, mutect2, varscan2
- ATG2B | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | catalogued as COSV100737849; called by muse, mutect2
- ATP10D | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV56703225; called by muse, varscan2
- ATP10D | c.1481del p.A494Efs*31 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as COSV56703231; called by pindel, varscan2
- ATP2B4 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58173944; called by muse, mutect2, varscan2
- ATP4A | c.302T>A p.V101D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52865150, COSV52869779; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59472159, COSV59472529; called by muse, mutect2, varscan2
- ATP7B | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs757341859, COSV54434742, COSV99666236; called by muse, mutect2, varscan2
- ATP8A2 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54934368; called by muse, mutect2, varscan2
- ATP9B | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.297); catalogued as COSV56944753; called by muse, mutect2, varscan2
- AVIL | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as rs977264026, COSV99142269; called by muse, mutect2, varscan2
- AXIN2 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.025); catalogued as rs1425391968, COSV100196282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT5 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197696, COSV58198021; called by muse, mutect2, varscan2
- B9D2 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs747988749, COSV54683499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAP1 | c.1730-1G>C p.X577_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV56229875, COSV56230270, COSV56241254; called by muse, mutect2, varscan2
- BCAP31 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV61451161; called by muse, mutect2, varscan2
- BCL2L11 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV58027627; called by muse, mutect2, varscan2
- BFSP1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); catalogued as rs779838677, COSV64899191; called by muse, mutect2, varscan2
- BIRC6 | c.9156G>C p.M3052I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV70194973, COSV70199208; called by muse, mutect2, varscan2
- BMP2K | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100621634; called by muse, mutect2, varscan2
- BPIFA3 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.043); catalogued as COSV64925560; called by muse, varscan2
- BRD4 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54581623; called by muse, mutect2, varscan2
- BRI3BP | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58295366; called by muse, mutect2, varscan2
- BSCL2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs149907021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs779437137, COSV56512420; called by muse, mutect2, varscan2
- BTBD17 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100945279; called by muse, mutect2, varscan2
- C10orf62 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV65705030; called by muse, mutect2, varscan2
- C2CD3 | c.4747G>C p.E1583Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs544451529, COSV58088985; called by muse, mutect2, varscan2
- C4BPB | c.661A>T p.N221Y | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54690625; called by muse, mutect2, varscan2
- C6orf120 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV59320839; called by muse, mutect2, varscan2
- C8orf76 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52689864, COSV52692705; called by muse, mutect2, varscan2
- C9orf131 | c.2765C>G p.S922* | Nonsense Mutation (SNP) | VAF 61/220 reads (28%) | catalogued as COSV100398000; called by muse, mutect2, varscan2
- CACNA1G | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV61719810; called by muse, mutect2, varscan2
- CAP1 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV61222662; called by muse, mutect2, varscan2
- CASP14 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.462); catalogued as rs750059845, COSV55664593; called by muse, mutect2, varscan2
- CCAR1 | c.3390G>C p.K1130N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.109); catalogued as COSV56266767; called by muse, mutect2, varscan2
- CCDC102A | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1350263446, COSV50775735; called by muse, mutect2, varscan2
- CCDC158 | c.2811-1G>C p.X937_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV66355044; called by muse, mutect2, varscan2
- CCDC180 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV63826326; called by muse, mutect2, varscan2
- CCDC54 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1370399650, COSV53757841; called by muse, mutect2, varscan2
- CCNB1 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV56509048; called by muse, mutect2, varscan2
- CCNT2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51470870; called by muse, mutect2, varscan2
- CCNYL1 | c.535G>C p.E179Q (on ENST00000295414 / NM_001330218.2; = p.E109Q on NM_152523.2) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV54938857; called by muse, mutect2, varscan2
- CCT6B | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV58487650; called by muse, mutect2
- CD163L1 | c.1703G>T p.R568I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV58010319, COSV58010401; called by muse, mutect2, varscan2
- CD2BP2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV59767989, COSV59769054, COSV59769344; called by muse, mutect2, varscan2
- CD46 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59731038; called by muse, mutect2, varscan2
- CDC20B | c.995C>G p.S332* | Nonsense Mutation (SNP) | VAF 36/68 reads (53%) | catalogued as COSV57056212; called by muse, mutect2, varscan2
- CDC42BPA | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62001195; called by muse, mutect2, varscan2
- CDH10 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs866850339, COSV52568304; called by muse, mutect2, varscan2
- CDK13 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV51695871, COSV99475472; called by muse, mutect2, varscan2
- CDK5RAP2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62571733; called by muse, mutect2, varscan2
- CDKN2A | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs121913382, COSV58682685, COSV58683250; called by muse, mutect2, varscan2
- CEACAM21 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51812742; called by muse, mutect2, varscan2
- CEACAM5 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55750369; called by muse, mutect2, varscan2
- CECR2 | c.2125G>A p.E709K (on ENST00000342247 / NM_001290047.2; = p.E526K on NM_001290046.1) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV52835320; called by muse, mutect2, varscan2
- CELF4 | c.1332C>T p.F444= | Splice Region (SNP) | VAF 20/70 reads (29%) | catalogued as rs1419294006, COSV58445367; called by muse, mutect2, varscan2
- CENATAC | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV57722030; called by muse, mutect2, varscan2
- CEP57L1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs760001448, COSV61243991; called by muse, mutect2, varscan2
- CEP68 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53123212; called by muse, mutect2, varscan2
- CFAP251 | c.2902C>G p.Q968E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV56607414; called by muse, mutect2, varscan2
- CFAP43 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.271); catalogued as COSV53375935; called by muse, mutect2, varscan2
- CFAP53 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV68351214; called by muse, mutect2, varscan2
- CFAP91 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV56338747, COSV56340830; called by muse, mutect2, varscan2
- CHFR | c.1391C>T p.S464F (on ENST00000432561 / NM_001161345.1; = p.S423F on NM_018223.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57171654; called by muse, mutect2, varscan2
- CHIT1 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV55145005; called by muse, mutect2, varscan2
- CHMP4C | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV51925894, COSV99794126; called by muse, mutect2, varscan2
- CHST8 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52855833; called by muse, mutect2, varscan2
- CIB2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.025); catalogued as COSV51947376; called by muse, mutect2, varscan2
- CKAP5 | c.4156G>A p.A1386T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV56363473; called by muse, mutect2, varscan2
- CKMT1B | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100294514; called by muse, mutect2, varscan2
- CLASP2 | c.3877G>C p.E1293Q (on ENST00000359576; = p.E1292Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV56275207; called by muse, mutect2, varscan2
- CLEC18B | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.833); catalogued as COSV60576274; called by muse, mutect2, varscan2
- CLEC1B | c.651G>C p.E217D | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV53724599, COSV53725323, COSV53726509; called by muse, mutect2, varscan2
- CLIP2 | c.2502G>C p.K834N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs782529309, COSV56273743; called by muse, mutect2, varscan2
- CLPX | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV55643068; called by muse, mutect2, varscan2
- CNGA2 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 74/108 reads (69%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.043); catalogued as COSV61702948; called by muse, mutect2, varscan2
- CNTN1 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100751611, COSV61635642; called by muse, mutect2, varscan2
- CNTRL | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53042611; called by muse, mutect2, varscan2
- CNTRL | c.4549G>C p.E1517Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.176); catalogued as COSV53042628, COSV53043540; called by muse, mutect2, varscan2
- COL22A1 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100281310, COSV57321171; called by muse, mutect2, varscan2
- COL27A1 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV61921023; called by muse, mutect2, varscan2
- COL5A3 | c.4391C>G p.S1464* | Nonsense Mutation (SNP) | VAF 44/161 reads (27%) | catalogued as COSV53408967, COSV53409257; called by muse, mutect2, varscan2
- COMMD9 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99661225; called by muse, mutect2, varscan2
- COP1 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV58162405; called by muse, mutect2, varscan2
- COPG1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV59112198; called by muse, mutect2, varscan2
- COPS4 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52313498; called by muse, mutect2, varscan2
- COQ6 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53177767; called by muse, mutect2, varscan2
- COQ9 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99345748; called by muse, mutect2
- CPA6 | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52719847; called by muse, mutect2, varscan2
- CPEB4 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99436917; called by muse, mutect2, varscan2
- CPNE1 | c.718G>A p.E240K (on ENST00000352393; = p.E245K on NM_003915.5) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58289508; called by muse, mutect2, varscan2
- CPNE4 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70189588; called by muse, mutect2, varscan2
- CPOX | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51637303; called by muse, mutect2, varscan2
- CRAT | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV58875738; called by muse, mutect2, varscan2
- CRB1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV66328503; called by muse, mutect2, varscan2
- CRCP | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV58534533; called by muse, mutect2, varscan2
- CREB3L4 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV55209132; called by muse, mutect2, varscan2
- CREB3L4 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV55131236; called by muse, mutect2, varscan2
- CSMD2 | c.7978G>A p.E2660K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.232); catalogued as COSV53874691; called by muse, mutect2, varscan2
- CTTN | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57229993; called by muse, mutect2, varscan2
- CUL9 | c.7078G>C p.E2360Q | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1280480500, COSV52724482; called by muse, mutect2, varscan2
- CXXC1 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs768273961, COSV53272933; called by muse, mutect2, varscan2
- CYP4F11 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as rs1206239930, COSV56125423; called by muse, mutect2, varscan2
- CYRIA | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1391594211, COSV62863601, COSV62867345; called by muse, mutect2, varscan2
- DCN | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV50005982, COSV50006596; called by muse, mutect2, varscan2
- DCP1A | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53686898; called by muse, mutect2, varscan2
- DDIT4L | c.92-1G>C p.X31_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99913855; called by muse, mutect2
- DDX4 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.977); catalogued as COSV61753160; called by muse, mutect2, varscan2
- DHX36 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57670551, COSV57670601; called by muse, mutect2, varscan2
- DIAPH2 | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100232052; called by muse, mutect2
- DICER1 | c.4401C>G p.I1467M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58615232; called by muse, mutect2, varscan2
- DIS3L | c.397G>C p.E133Q (on ENST00000319212 / NM_001143688.3; = p.E50Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59910823; called by muse, mutect2, varscan2
- DLG1 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58377107; called by muse, mutect2, varscan2
- DNAH10 | c.2893G>C p.E965Q (on ENST00000409039; = p.E904Q on NM_207437.3) | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV68987247, COSV68999975; called by muse, mutect2, varscan2
- DNAH11 | c.4316G>A p.R1439K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60937217; called by muse, mutect2, varscan2
- DNAH17 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67749173; called by muse, mutect2, varscan2
- DNAH5 | c.2681C>G p.S894C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV54201489; called by mutect2, varscan2
- DNAH9 | c.9725G>A p.R3242K | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV52331827; called by muse, mutect2, varscan2
- DNAI3 | c.2542C>G p.Q848E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54000308, COSV99038153; called by muse, mutect2, varscan2
- DNAJC21 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV57758934; called by muse, mutect2, varscan2
- DNMT3A | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53036432; called by muse, mutect2, varscan2
- DOCK8 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.562); catalogued as COSV66632830, COSV66636081; called by muse, mutect2, varscan2
- DOP1B | c.4839G>C p.L1613F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV67691871; called by muse, mutect2, varscan2
- DSP | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs1302759290, COSV65790810; called by muse, mutect2, varscan2
- DST | c.21577G>A p.D7193N (on ENST00000361203 / NM_001374722.1; = p.D4890N on NM_015548.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV54995497; called by muse, mutect2, varscan2
- DST | c.19774G>A p.D6592N (on ENST00000361203 / NM_001374722.1; = p.D4289N on NM_015548.5) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV54995514; called by muse, mutect2, varscan2
- DST | c.9079C>T p.L3027F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.102); catalogued as COSV54995527; called by muse, mutect2, varscan2
- DXO | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV61712691; called by muse, mutect2, varscan2
- DYNC1I1 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV61454956; called by muse, varscan2
- DYRK1A | c.651G>C p.M217I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.682); catalogued as COSV100118342, COSV58292160; called by muse, mutect2, varscan2
- EDAR | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV51499574; called by muse, mutect2, varscan2
- EFCAB13 | c.2202G>C p.L734F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58945300; called by muse, mutect2, varscan2
- EGFLAM | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59292085; called by muse, mutect2, varscan2
- EHBP1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as COSV50415473; called by muse, mutect2, varscan2
- EHBP1 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); catalogued as rs775687781, COSV104381876, COSV50415477; called by muse, mutect2, varscan2
- EIF2S1 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV53604053, COSV53605249; called by muse, mutect2, varscan2
- EIF3F | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 48/178 reads (27%) | catalogued as COSV100562502; called by muse, varscan2
- EIF5B | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99177021; called by muse, mutect2, varscan2
- ELAVL1 | c.306delinsAA p.I103Nfs*53 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | catalogued as COSV60965643; called by mutect2*, pindel, varscan2*
- ELAVL3 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV63644979; called by muse, mutect2, varscan2
- EMC10 | c.186C>T p.I62= | Splice Region (SNP) | VAF 16/60 reads (27%) | catalogued as rs371024737; called by muse, mutect2, varscan2
- ENO2 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV50386572; called by muse, mutect2, varscan2
- ENTPD6 | c.1047G>A p.A349= | Splice Region (SNP) | VAF 41/141 reads (29%) | catalogued as rs896694181, COSV61750800; called by muse, mutect2, varscan2
- EP300 | c.6361C>T p.Q2121* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99608042; called by muse, mutect2, varscan2
- EPHB2 | c.1702C>T p.R568W (on ENST00000400191 / NM_001309193.2; = p.R569W on NM_004442.7) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs200219468, CM065141; called by muse, mutect2, varscan2
- ETNK1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV56883371; called by muse, mutect2, varscan2
- EXOC2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV57860698; called by muse, mutect2, varscan2
- EXOC3L2 | c.2242C>G p.R748G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52971834; called by muse, mutect2, varscan2
- EXOC6B | c.2037G>C p.L679F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55543612; called by muse, mutect2, varscan2
- EXPH5 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs760324161, COSV56198477, COSV56198612; called by muse, mutect2, varscan2
- EXT2 | c.1492G>A p.E498K (on ENST00000343631; = p.E531K on NM_000401.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.082); catalogued as COSV100640566; called by muse, mutect2
- EYA2 | c.933G>C p.M311I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV57937497, COSV57944506; called by muse, mutect2, varscan2
- F13B | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV66372019; called by muse, mutect2, varscan2
- FAAH | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV54542904; called by muse, mutect2, varscan2
- FAM111A | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100659439, COSV64654963, COSV64655938; called by muse, mutect2, varscan2
- FAM117A | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99544587; called by muse, varscan2
- FAM180A | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100647248; called by muse, mutect2
- FAM180A | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1001328413, COSV58527707, COSV58527910; called by muse, mutect2, varscan2
- FAM234A | c.1110G>C p.L370= | Splice Region (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51451300; called by muse, mutect2, varscan2
- FAM234A | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV51451311; called by muse, mutect2, varscan2
- FAM43A | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV61672578; called by muse, mutect2, varscan2
- FAM76A | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99159251; called by muse, mutect2, varscan2
- FAT2 | c.5991G>C p.L1997F | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV55812373; called by muse, mutect2, varscan2
- FAT4 | c.6688C>A p.Q2230K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as rs758534993, COSV58669859, COSV58714247; called by muse, mutect2, varscan2
- FBF1 | c.3146C>T p.S1049F (on ENST00000586717; = p.S1064F on NM_001319193.1) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.66); catalogued as COSV59863447; called by muse, varscan2
- FBLN5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as COSV50902008; called by muse, mutect2, varscan2
- FBN1 | c.3083-1G>T p.X1028_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | catalogued as CS157713, COSV57308126; called by muse, mutect2, varscan2
- FBXO41 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1558584321, COSV99721100; called by mutect2, varscan2
- FBXO6 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100950992; called by muse, mutect2, varscan2
- FCGR2C | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.995); catalogued as COSV100912636; called by muse, mutect2, varscan2
- FGD6 | c.3902C>T p.S1301L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59689916; called by muse, mutect2, varscan2
- FHIT | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV59282910, COSV59285524; called by muse, mutect2, varscan2
- FLNB | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55868962; called by muse, varscan2
- FMO1 | c.693G>A p.W231* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100707728; called by muse, mutect2, varscan2
- FNBP4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55445652; called by muse, mutect2, varscan2
- FNDC8 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1361193329, COSV50100428; called by muse, mutect2, varscan2
- FOXP3 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV66050727; called by muse, mutect2, varscan2
- FRMD4B | c.2781G>C p.Q927H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68328056; called by muse, mutect2, varscan2
- FRMPD1 | c.2711T>G p.L904R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as COSV66698959; called by muse, mutect2, varscan2
- FRMPD3 | c.1317C>A p.F439L | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52185810; called by muse, mutect2, varscan2
- FSCB | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV61216291; called by muse, mutect2, varscan2
- FYCO1 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56113106; called by muse, varscan2
- FYCO1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56113118, COSV56115086; called by muse, varscan2
- GAN | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 59/229 reads (26%) | catalogued as COSV101633972; called by muse, mutect2, varscan2
- GCM1 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1415289240, COSV52520591; called by muse, mutect2, varscan2
- GDPD1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV52380489; called by muse, mutect2, varscan2
- GIT1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV56401614; called by muse, mutect2, varscan2
- GJA3 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53833967, COSV53835283; called by muse, mutect2, varscan2
- GLI2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs145779352; called by muse, mutect2, varscan2
- GMIP | c.2496G>T p.Q832H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52553904; called by muse, mutect2, varscan2
- GNA13 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (1); catalogued as COSV71474327; called by muse, mutect2, varscan2
- GNPTAB | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54776388; called by muse, mutect2, varscan2
- GOLGA3 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs375782880; called by muse, mutect2, varscan2
- GPD2 | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100133114; called by muse, mutect2, varscan2
- GPR149 | c.1038C>G p.F346L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67665517, COSV67666666; called by muse, mutect2, varscan2
- GPSM2 | c.1925G>A p.R642K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51440758; called by muse, varscan2
- GPSM2 | c.1955G>A p.R652K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.239); catalogued as COSV51440771, COSV51444810; called by muse, varscan2
- GPT | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 142/508 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767300625, COSV52952069; called by muse, mutect2, varscan2
- GRB14 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55735097; called by muse, mutect2, varscan2
- GRID2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56168095; called by muse, mutect2, varscan2
- GRIK3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV66134937; called by muse, mutect2, varscan2
- GRK2 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 104/376 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV57750493; called by muse, mutect2, varscan2
- GRK7 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53821395; called by muse, mutect2, varscan2
- GRM1 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51107901; called by muse, mutect2, varscan2
- GRXCR1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV67669770; called by muse, mutect2, varscan2
- GTF2I | c.1358C>T p.S453L (on ENST00000573035 / NM_032999.4; = p.S412L on NM_001518.5) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV60398951; called by muse, mutect2, varscan2
- GTPBP2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV61077167; called by muse, mutect2
- H2BC7 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2, varscan2
- H3C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- H4C12 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- H4C6 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs1284645428, COSV66685362; called by muse, mutect2, varscan2
- HAO2 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58037676; called by muse, mutect2, varscan2
- HCK | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52940056; called by muse, mutect2, varscan2
- HCN3 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100712807, COSV61360221; called by muse, mutect2, varscan2
- HDHD3 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV53056431, COSV53057861; called by muse, mutect2, varscan2
- HDLBP | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.224); catalogued as COSV60491594; called by muse, mutect2, varscan2
- HEATR1 | c.3307C>T p.Q1103* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100857578; called by muse, mutect2, varscan2
- HELQ | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs1051313802, COSV55023935; called by muse, mutect2, varscan2
- HIF3A | c.799G>A p.D267N (on ENST00000377670 / NM_152795.4; = p.D198N on NM_022462.4) | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs764768309, COSV52195434; called by muse, mutect2, varscan2
- HIVEP2 | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV50005281, COSV50010400; called by muse, mutect2, varscan2
- HLA-F | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV52574388; called by muse, mutect2, varscan2
- HMCN1 | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV54873277, COSV54913746; called by muse, mutect2, varscan2
- HMGCR | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV55314254; called by muse, mutect2, varscan2
- HOXA6 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV56071876; called by muse, mutect2, varscan2
- HOXD12 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66832262; called by muse, mutect2, varscan2
- HPS4 | c.1775G>C p.R592T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as COSV61102378, COSV61105960; called by muse, mutect2, varscan2
- HPX | c.435del p.A146Lfs*32 | Frame Shift Del (DEL) | VAF 48/188 reads (26%) | catalogued as COSV56418370; called by mutect2, pindel, varscan2
- HSD3B1 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV52489493; called by muse, mutect2, varscan2
- HSPA5 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV52333908; called by muse, mutect2, varscan2
- HSPA5 | c.1029G>C p.Q343H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV52333918, COSV52334853; called by muse, mutect2, varscan2
- HSPA5 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV52333923; called by muse, mutect2, varscan2
- HTR2A | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs763899284, COSV66326523; called by muse, mutect2, varscan2
- HYAL4 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs769948388, COSV56137425; called by muse, mutect2, varscan2
- HYDIN | c.9154G>A p.E3052K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99992426, COSV99993074; called by muse, mutect2
- IGHV5-51 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1555541473; called by muse, mutect2, varscan2
- IGIP | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1236575327, COSV60963944, COSV60964748; called by muse, mutect2, varscan2
- IL1F10 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 123/449 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV61750261; called by muse, mutect2, varscan2
- IL22RA1 | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54627462; called by muse, mutect2, varscan2
- ILF2 | c.1135C>G p.Q379E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV62626659; called by muse, mutect2, varscan2
- IMMT | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54477814, COSV54481775; called by muse, mutect2, varscan2
- ING4 | c.369C>A p.S123R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV58553983; called by muse, mutect2, varscan2
- IQCC | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.221); catalogued as COSV52207266; called by muse, mutect2, varscan2
- ITGA8 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as COSV100959067; called by muse, mutect2, varscan2
- ITSN2 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV61945119, COSV61954259; called by muse, mutect2, varscan2
- ITSN2 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100743088; called by muse, mutect2, varscan2
- JCAD | c.3379G>C p.E1127Q | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as COSV64757696; called by muse, mutect2, varscan2
- JMY | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.44); catalogued as rs752940556, COSV68659175; called by muse, mutect2, varscan2
- JRK | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.367); catalogued as rs781793972, COSV101401074; called by muse, mutect2
- KAT2A | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs782448055, COSV52427059; called by muse, mutect2
- KCNC4 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 101/132 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1349133027, COSV63924864; called by muse, mutect2, varscan2
- KCNH5 | c.2845C>T p.Q949* | Nonsense Mutation (SNP) | VAF 68/203 reads (33%) | catalogued as COSV100525969; called by muse, mutect2, varscan2
- KCNH7 | c.3291C>G p.I1097M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV59782866; called by muse, mutect2, varscan2
- KDM1B | c.985C>T p.Q329* (on ENST00000449850; = p.Q197* on NM_153042.4) | Nonsense Mutation (SNP) | VAF 31/145 reads (21%) | catalogued as COSV99924115; called by muse, mutect2, varscan2
- KDSR | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV58505876; called by muse, mutect2, varscan2
- KERA | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV57129824; called by muse, mutect2, varscan2
- KIAA0753 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as rs773280909, COSV100810560; called by muse, mutect2, varscan2
- KIAA1109 | c.5842G>C p.D1948H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52661117; called by muse, mutect2, varscan2
- KIF13B | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV73054143; called by muse, mutect2
- KLHL11 | c.2070G>C p.E690D | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.185); catalogued as COSV59861284; called by muse, mutect2, varscan2
- KLHL11 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV59861296; called by muse, mutect2, varscan2
- KLHL11 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV59861305; called by muse, mutect2, varscan2
- KLHL11 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100044252; called by muse, mutect2, varscan2
- KMT2D | c.12943C>T p.Q4315* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99979432; called by muse, mutect2, varscan2
- KMT5B | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58563348; called by muse, mutect2, varscan2
- KPTN | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as COSV57644205; called by muse, varscan2
- KRI1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57263376; called by muse, mutect2, varscan2
- KRT222 | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67497684; called by muse, mutect2, varscan2
- KRT24 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.699); catalogued as rs775417089, COSV52879406; called by muse, mutect2, varscan2
- L3MBTL2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.037); catalogued as COSV53431473; called by muse, mutect2, varscan2
- LAMC2 | c.2639C>T p.S880L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV51452054; called by muse, mutect2, varscan2
- LANCL1 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52063861; called by muse, mutect2, varscan2
- LEMD1 | c.468G>C p.L156F (on ENST00000367151; = p.*109Sext*16 on NM_001001552.5) | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100903449; called by muse, mutect2, varscan2
- LHFPL2 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs1029122117, COSV66713436, COSV66716551; called by muse, varscan2
- LHFPL2 | c.453G>C p.L151F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66713444; called by muse, varscan2
- LHX1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs780940543; called by muse, mutect2, varscan2
- LIPE | c.2393C>G p.S798* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV99733974; called by muse, mutect2, varscan2
- LMBR1 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62218031; called by muse, mutect2, varscan2
- LRBA | c.2978C>G p.S993* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1329983907, CM160679, COSV63966506; called by muse, mutect2, varscan2
- LRP1B | c.4638C>G p.I1546M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV101249256, COSV67182220; called by muse, mutect2, varscan2
- LRP1B | c.124C>G p.H42D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.043); catalogued as COSV67182226; called by muse, mutect2, varscan2
- LRP6 | c.53G>C p.R18T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54380990; called by mutect2, varscan2
- LRRC66 | c.2087G>A p.C696Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58631808, COSV58635149; called by muse, mutect2, varscan2
- LRRC66 | c.235C>G p.H79D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV58631823; called by muse, mutect2
- LRRC74A | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV53607606; called by muse, mutect2, varscan2
- LRRCC1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs768909297, COSV64482480; called by muse, mutect2, varscan2
- LRRK1 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV52599987; called by muse, mutect2, varscan2
- LRRK1 | c.5230G>C p.E1744Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV52600009; called by muse, mutect2, varscan2
- LRTM2 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- LSMEM2 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV57112431; called by muse, mutect2, varscan2
- LTO1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1245524822, COSV54162453, COSV99654181; called by muse, mutect2, varscan2
- LUC7L3 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53585291; called by muse, mutect2, varscan2
- LUC7L3 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53585306; called by muse, mutect2, varscan2
- LYST | c.11143G>C p.E3715Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67702726; called by muse, mutect2, varscan2
- LYST | c.4579C>G p.P1527A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV67702731; called by muse, mutect2, varscan2
- LZTS1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.708); catalogued as rs749091977, COSV56115620; called by muse, mutect2, varscan2
- MADD | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1565321490, COSV60619866; called by muse, mutect2, varscan2
- MAGEC1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.641); catalogued as rs1248359822, COSV53567287; called by muse, mutect2
- MAP3K4 | c.2411T>A p.L804H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62329837; called by muse, mutect2, varscan2
- MAP6 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59073884, COSV59075834; called by muse, mutect2, varscan2
- MAPK7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV55189099; called by muse, mutect2, varscan2
- MBTD1 | c.1053C>G p.F351L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1257899673, COSV100899142, COSV64502633; called by muse, mutect2, varscan2
- MC3R | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV54762877; called by muse, mutect2, varscan2
- MCM8 | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54509832; called by muse, mutect2, varscan2
- MCOLN3 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV62012939; called by muse, mutect2, varscan2
- MED12 | c.5362A>G p.K1788E | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV61329390; called by muse, mutect2, varscan2
- MED12 | c.5751G>A p.Q1917= | Splice Region (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100377095, COSV100377523; called by muse, mutect2, varscan2
- MED15 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53026469; called by muse, mutect2, varscan2
- MED15 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99487260, COSV99487542; called by muse, varscan2
- MEX3A | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV68478917; called by muse, mutect2, varscan2
- MEX3A | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV68478920; called by muse, mutect2, varscan2
- MFN1 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as COSV99764334; called by muse, mutect2
- MFSD8 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754403098, COSV56549964; called by muse, mutect2, varscan2
- MGAM | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs947903146, COSV72073457, COSV72074882; called by muse, mutect2, varscan2
- MICAL2 | c.2279C>A p.S760Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV56315931; called by muse, mutect2, varscan2
- MMP16 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99687078; called by muse, mutect2, varscan2
- MOCS3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54865478; called by muse, mutect2, varscan2
- MORC1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138435095, COSV51713000; called by muse, mutect2, varscan2
- MORC4 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV55239114; called by muse, mutect2, varscan2
- MORN3 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV62506973; called by muse, mutect2, varscan2
- MPDZ | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1455520567, COSV59934837, COSV59936526; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3472G>C p.E1158Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616283; called by muse, mutect2, varscan2
- MRAP2 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV57631304, COSV57634296; called by muse, mutect2, varscan2
- MROH2B | c.4368G>C p.L1456F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as COSV68180682; called by muse, mutect2, varscan2
- MRPL58 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV56900172; called by muse, mutect2, varscan2
- MRPS30 | c.1159A>T p.N387Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50181465; called by muse, mutect2, varscan2
- MSH6 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV52273512; called by muse, mutect2, varscan2
- MTO1 | c.1609G>C p.E537Q (on ENST00000370300 / NM_133645.3; = p.E512Q on NM_012123.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV64772982; called by muse, mutect2, varscan2
- MUC16 | c.20861G>A p.R6954K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV67441213; called by muse, mutect2, varscan2
- MUC16 | c.20551G>A p.E6851K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as rs61995732, COSV67441224; called by muse, mutect2, varscan2
- MUC16 | c.5495C>G p.S1832C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV67441241; called by muse, mutect2, varscan2
- MYH15 | c.3973G>T p.E1325* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV99842831; called by muse, mutect2, varscan2
- MYH6 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs747945067, COSV62447595; called by muse, mutect2, varscan2
- MYNN | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV62990904; called by muse, mutect2, varscan2
- MYO15A | c.9401G>A p.R3134Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373695303; called by muse, mutect2, varscan2
- MYO18B | c.7412C>G p.S2471* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100123134; called by muse, mutect2, varscan2
- MYO1A | c.2264G>C p.R755T | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55651451; called by muse, mutect2, varscan2
- MYO1F | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV57791484; called by muse, mutect2, varscan2
- MYO3A | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56318243, COSV99779145; called by muse, mutect2, varscan2
- MYO7B | c.5719G>C p.D1907H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61441247; called by muse, mutect2, varscan2
- MYOCD | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV58496613, COSV58507730; called by muse, mutect2, varscan2
- MYOT | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV51794423; called by muse, mutect2, varscan2
- MYPOP | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV59132965; called by muse, mutect2, varscan2
- MZF1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1462063492, COSV53040476; called by muse, mutect2, varscan2
- N4BP2 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54698478; called by muse, mutect2, varscan2
- NADK2 | c.563C>T p.S188F (on ENST00000381937 / NM_001085411.3; = p.S25F on NM_153013.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56934962; called by muse, mutect2, varscan2
- NAE1 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV51974820; called by muse, mutect2, varscan2
- NAP1L2 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs773969675, COSV65172055; called by muse, mutect2, varscan2
- NAT8 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV55542117, COSV55543225; called by muse, mutect2, varscan2
- NBEAL1 | c.6823C>G p.Q2275E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58719541; called by muse, mutect2, varscan2
- NCAM2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs868144893, COSV53053735; called by muse, mutect2, varscan2
- NCF2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV62314743; called by muse, mutect2, varscan2
- NDUFA13 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.248); catalogued as COSV53062372; called by muse, mutect2, varscan2
- NDUFA9 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99865440; called by muse, mutect2, varscan2
- NDUFB4 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as COSV51741691; called by muse, mutect2, varscan2
- NES | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 150/533 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63960251; called by muse, mutect2, varscan2
- NETO2 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.327); catalogued as COSV57451138; called by muse, mutect2, varscan2
- NHSL2 | c.1866G>T p.Q622H (on ENST00000510661; = p.Q988H on NM_001013627.2) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65452236; called by muse, mutect2, varscan2
- NID1 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV51614285; called by muse, mutect2, varscan2
- NID2 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV99356231, COSV99357221; called by muse, mutect2, varscan2
- NKX2-5 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV100234778; called by muse, mutect2
- NLRP1 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.358); catalogued as COSV52557525; called by muse, mutect2, varscan2
- NOS2 | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); catalogued as COSV58221384; called by muse, mutect2, varscan2
- NPHP1 | c.1705G>A p.E569K (on ENST00000393272 / NM_207181.4; = p.E570K on NM_000272.5) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100337938; called by muse, mutect2
- NPHP4 | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV65392860; called by muse, mutect2, varscan2
- NPRL2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs1206641194, COSV51599729; called by muse, mutect2, varscan2
- NUP153 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs774013222, COSV50446020; called by muse, mutect2, varscan2
- NUP210 | c.5157G>C p.E1719D | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54401909; called by muse, mutect2, varscan2
- NUSAP1 | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52969813; called by muse, mutect2, varscan2
- NXPH1 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68310643; called by muse, mutect2, varscan2
- OBSCN | c.11974G>A p.E3992K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99475642; called by muse, mutect2
- OBSCN | c.12116G>C p.G4039A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV52735651; called by muse, mutect2, varscan2
- OPA3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.525); catalogued as COSV54397830, COSV54398681; called by muse, mutect2, varscan2
- OPRK1 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV55567978; called by muse, mutect2, varscan2
- OPTN | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99537374, COSV99537871; called by muse, mutect2, varscan2
- OR10A2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56298595; called by muse, mutect2, varscan2
- OR10A6 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143603778; called by muse, mutect2, varscan2
- OR2G2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as COSV60739212; called by muse, mutect2, varscan2
- OR2G3 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60680663; called by muse, mutect2, varscan2
- OR2J2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs767754730, COSV101013323; called by muse, mutect2, varscan2
- OR52B6 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV61447135; called by muse, mutect2, varscan2
- OR5AN1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1164183152, COSV58321510; called by muse, mutect2, varscan2
- OR5M8 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59115587; called by muse, mutect2, varscan2
- OR7C1 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV50182827; called by muse, mutect2, varscan2
- OTOGL | c.3376C>G p.Q1126E (on ENST00000547103; = p.Q1117E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV72005530, COSV72006624; called by muse, mutect2, varscan2
- P4HA1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54958041; called by muse, varscan2
- PABPC1L | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV53838484, COSV53838972; called by muse, mutect2, varscan2
- PAK5 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868564987, COSV62019951; called by muse, mutect2, varscan2
- PALM | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); catalogued as rs771024183, COSV52766346; called by muse, mutect2, varscan2
- PAN2 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.26); catalogued as COSV57752469; called by muse, mutect2, varscan2
- PAPPA2 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62772081; called by muse, mutect2, varscan2
- PAQR3 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV55008275; called by muse, mutect2, varscan2
- PAQR6 | c.727G>T p.E243* (on ENST00000292291 / NM_001272108.2; = p.E137* on NM_024897.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV52744939, COSV99430938; called by muse, mutect2, varscan2
- PCCB | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV52443242; called by muse, mutect2, varscan2
- PCDH9 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60524551; called by muse, mutect2, varscan2
- PDHB | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234397875, COSV57056206; called by muse, mutect2, varscan2
- PDS5A | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs746027697, COSV57821931; called by muse, mutect2, varscan2
- PELI2 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50709822; called by muse, mutect2, varscan2
- PELP1 | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV52585452; called by muse, mutect2, varscan2
- PER3 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); catalogued as rs758407133, COSV62704124; called by muse, mutect2, varscan2
- PEX1 | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780992963, COSV50394483, COSV50404871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGBD5 | c.365G>A p.G122E (on ENST00000525115; = p.G191E on NM_001258311.2) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.305); catalogued as COSV100358350, COSV58410348; called by muse, mutect2, varscan2
- PGD | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54620055; called by muse, mutect2, varscan2
- PHF20L1 | c.2196G>C p.Q732H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55188149; called by muse, mutect2, varscan2
- PHF3 | c.3256G>C p.E1086Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV50312886; called by muse, mutect2, varscan2
- PHIP | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51501092; called by muse, mutect2, varscan2
- PHLPP2 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); catalogued as rs958787081, COSV62422220; called by muse, mutect2, varscan2
- PICALM | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62668906; called by muse, mutect2, varscan2
- PIDD1 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.761); catalogued as COSV61704003; called by muse, mutect2
- PIGS | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV52023284, COSV52025960; called by muse, varscan2
- PIK3R3 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV53103938; called by muse, mutect2, varscan2
- PIK3R5 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs780942089, COSV52650108; called by muse, mutect2, varscan2
- PKHD1 | c.12180C>G p.F4060L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100944625, COSV64380574; called by muse, mutect2, varscan2
- PLA2G6 | c.1425G>A p.R475= | Splice Region (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59267651; called by muse, mutect2, varscan2
- PLA2R1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51774313; called by muse, mutect2, varscan2
- PLEKHA5 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54693335; called by muse, mutect2, varscan2
- PLEKHG4B | c.3198G>C p.L1066F (on ENST00000283426; = p.L1422F on NM_052909.5) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV52042890; called by muse, mutect2, varscan2
- PLEKHG5 | c.379G>C p.E127Q (on ENST00000400915 / NM_001042663.3; = p.E90Q on NM_020631.6) | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61699802; called by muse, mutect2, varscan2
- PLG | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV51980414, COSV99804558; called by muse, mutect2, varscan2
- PLXDC2 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 52/261 reads (20%) | catalogued as COSV101022862; called by muse, mutect2, varscan2
- PLXNA4 | c.4845G>C p.R1615S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as rs758015320, COSV58102419, COSV58142345; called by muse, mutect2, varscan2
- POLE | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 29/82 reads (35%) | catalogued as rs1431917980, COSV57673192; called by muse, mutect2, varscan2
- POLQ | c.6811C>G p.Q2271E | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV51745015; called by muse, mutect2, varscan2
- PPHLN1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV56727885; called by muse, mutect2, varscan2
- PPM1K | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55794811; called by muse, mutect2
- PRKDC | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV58041206; called by muse, mutect2, varscan2
- PRKG1 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64765887, COSV64778012; called by muse, mutect2, varscan2
- PRMT8 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV54211279; called by muse, mutect2, varscan2
- PRR12 | c.914C>G p.S305C (on ENST00000615927; = p.S1126C on NM_020719.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69816514; called by muse, mutect2, varscan2
- PRR3 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100925406; called by muse, mutect2, varscan2
- PRRC2A | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV52987581; called by muse, mutect2, varscan2
- PRRC2B | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.197); catalogued as COSV61933520; called by muse, mutect2, varscan2
- PRRT1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99278323; called by muse, mutect2, varscan2
- PRSS58 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV73488421, COSV73488761; called by muse, mutect2, varscan2
- PRX | c.3238C>T p.R1080C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs200045096, COSV52518809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG4 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54932426, COSV54933368; called by muse, mutect2, varscan2
- PTEN | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV64288409; called by mutect2, varscan2
- PTPN13 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as COSV57401681; called by muse, mutect2, varscan2
- PTPRC | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 31/127 reads (24%) | catalogued as COSV100722364; called by muse, mutect2, varscan2
- PTPRC | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1191758134, COSV61405688; called by muse, mutect2, varscan2
- PTPRC | c.3574G>C p.E1192Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405703; called by muse, mutect2, varscan2
- PTPRS | c.5517C>G p.F1839L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53608505; called by muse, mutect2, varscan2
- PTPRT | c.2571G>C p.E857D | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV61957537; called by muse, mutect2, varscan2
- PYROXD1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1440433766, COSV53707864; called by muse, mutect2, varscan2
- RAB30 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.204); catalogued as COSV52625648; called by muse, mutect2, varscan2
- RAB9B | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 110/181 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54587097; called by muse, mutect2, varscan2
- RADX | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.899); catalogued as COSV65317644; called by muse, mutect2, varscan2
- RANBP2 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51695589, COSV51705617; called by muse, mutect2, varscan2
- RANBP9 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 95/228 reads (42%) | catalogued as COSV99163509; called by muse, mutect2, varscan2
- RAP1GDS1 | c.402G>T p.Q134H (on ENST00000408927 / NM_001100427.2; = p.Q135H on NM_021159.5) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs940050790, COSV52783985; called by muse, mutect2, varscan2
- RB1 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as CM1312467, COSV57305995; called by muse, mutect2
- RBBP7 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 42/58 reads (72%) | catalogued as COSV100417846; called by muse, mutect2, varscan2
- RBM46 | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV55982230; called by mutect2, varscan2
- RBMXL1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.907); catalogued as COSV53097906, COSV53103829; called by muse, mutect2, varscan2
- RELN | c.7141G>A p.D2381N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV58983808; called by muse, mutect2, varscan2
- RFX2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV57938804; called by muse, mutect2, varscan2
- RFX5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV51837858; called by muse, mutect2, varscan2
- RIMS2 | c.4166C>A p.S1389Y (on ENST00000666250 / NM_001348490.2; = p.S960Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51649892, COSV51712228; called by muse, mutect2, varscan2
- RIOX1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100407995; called by muse, mutect2, varscan2
- RLF | c.4744G>C p.E1582Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV65650408; called by muse, mutect2, varscan2
- RNF13 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as rs781271591, COSV53522601; called by muse, mutect2, varscan2
- RNF148 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs1458113954; called by muse, mutect2
- RNF213 | c.7385C>G p.S2462C | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60388760; called by muse, mutect2, varscan2
- RNF216 | c.1082C>G p.S361C (on ENST00000425013 / NM_207116.3; = p.S418C on NM_207111.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs144615363; called by muse, mutect2, varscan2
- RNF220 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 137/402 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62404408, COSV62404590; called by muse, mutect2, varscan2
- ROBO2 | c.1438-1G>A p.X480_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100165509, COSV59909858; called by muse, mutect2
- ROBO3 | c.3832G>C p.E1278Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.33); catalogued as COSV60620946; called by muse, mutect2, varscan2
- RORA | c.1100G>C p.R367T (on ENST00000335670 / NM_134261.3; = p.R392T on NM_002943.3) | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55035093, COSV99832232; called by muse, mutect2, varscan2
- RPL10L | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.602); catalogued as COSV53558499; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1412569809, COSV59086947; called by muse, mutect2, varscan2
- RPL29 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV53685505, COSV53685601; called by muse, varscan2
- RPRD2 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64815937; called by muse, mutect2, varscan2
- RPRM | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1196453867, COSV57988436; called by muse, mutect2, varscan2
- RPS6KA6 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV53115594; called by muse, mutect2, varscan2
- RSPH10B2 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV51867434; called by muse, mutect2, varscan2
- RSRC1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs372306685; called by muse, mutect2, varscan2
- RTN4 | c.3048G>C p.K1016N (on ENST00000337526 / NM_020532.5; = p.K23N on NM_007008.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58264307, COSV58264688; called by muse, mutect2, varscan2
- RTTN | c.6110C>G p.S2037* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV99731757; called by muse, mutect2, varscan2
- RUBCN | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs757331812, COSV56362101; called by muse, mutect2, varscan2
- RUSC2 | c.3909G>C p.K1303N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV63427485; called by muse, mutect2, varscan2
- RXRB | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV63399950; called by muse, mutect2
- RXYLT1 | c.404C>G p.S135* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99706794; called by muse, mutect2, varscan2
- RYR2 | c.6312G>C p.K2104N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63657530, COSV63686601; called by muse, mutect2, varscan2
- S100PBP | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100758333; called by muse, mutect2
- SACS | c.11035C>G p.L3679V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66533223, COSV66540228; called by muse, mutect2, varscan2
- SALL4 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV53849530; called by muse, mutect2, varscan2
- SAMD11 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV58985694; called by muse, mutect2
- SAMD9L | c.2117C>G p.S706C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV59079129, COSV59081259; called by muse, mutect2, varscan2
- SAP130 | c.2969G>A p.R990Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.933); catalogued as rs1034934642, COSV52093780; called by muse, mutect2, varscan2
- SCAF8 | c.2867C>T p.S956L | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as rs753495761, COSV65789710; called by muse, mutect2, varscan2
- SCG3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99590832; called by muse, mutect2, varscan2
- SCIMP | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV68310711; called by muse, mutect2, varscan2
- SCMH1 | c.1172C>G p.S391C (on ENST00000326197 / NM_001031694.2; = p.S344C on NM_012236.4) | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58231870; called by muse, mutect2, varscan2
- SCTR | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV50026714; called by muse, mutect2, varscan2
- SDE2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV55249507; called by muse, mutect2, varscan2
- SDE2 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55249529, COSV55250135; called by muse, mutect2, varscan2
- SDHAF2 | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 46/168 reads (27%) | catalogued as COSV100073920; called by muse, mutect2, varscan2
- SEC14L1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.304); catalogued as COSV66720677; called by muse, mutect2, varscan2
- SEC23A | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV56970134; called by muse, mutect2, varscan2
- SEC62 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100427857, COSV100427914; called by muse, mutect2, varscan2
- SELENOH | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53553115; called by muse, mutect2, varscan2
- SERBP1 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV100769072; called by muse, mutect2, varscan2
- SERINC3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.568); catalogued as COSV54855261; called by muse, mutect2, varscan2
- SESN1 | c.465G>C p.E155D (on ENST00000356644 / NM_001199933.1; = p.E214D on NM_014454.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV57420163; called by muse, mutect2, varscan2
- SEZ6L | c.3068C>G p.S1023C | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50657624; called by muse, mutect2, varscan2
- SFI1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs1449062961, COSV66289496; called by muse, mutect2, varscan2
- SGSM2 | c.1829G>T p.W610L (on ENST00000426855 / NM_001098509.2; = p.W655L on NM_014853.3) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52155545; called by muse, mutect2, varscan2
- SGSM3 | c.1805G>C p.R602T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs776123242, COSV50651135; called by muse, mutect2, varscan2
- SH3PXD2A | c.2392G>A p.E798K (on ENST00000369774 / NM_001365079.1; = p.E770K on NM_014631.2) | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV60115295; called by muse, mutect2, varscan2
- SH3TC1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV55280764, COSV99795220; called by muse, mutect2, varscan2
- SHH | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV99793200, COSV99793344; called by muse, mutect2
- SHOC1 | c.3527C>G p.S1176* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100597443; called by muse, mutect2
- SI | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.305); catalogued as COSV52264461, COSV52266694; called by muse, mutect2, varscan2
- SIGLEC1 | c.2875C>A p.H959N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450235800, COSV52458028, COSV52463390; called by muse, mutect2, varscan2
- SIM2 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51765707; called by muse, mutect2, varscan2
- SIN3B | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs551562375, COSV56130850, COSV99931275; called by muse, mutect2, varscan2
- SIPA1L2 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99477706; called by muse, mutect2, varscan2
- SKIDA1 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as COSV101481273; called by muse, mutect2, varscan2
- SKIDA1 | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1451276474, COSV71610396; called by muse, mutect2, varscan2
- SLC1A6 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV55667488; called by muse, mutect2, varscan2
- SLC22A9 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV54165500; called by muse, mutect2, varscan2
- SLC24A2 | c.747G>C p.L249F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856378; called by muse, mutect2, varscan2
- SLC26A3 | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60638398, COSV60640497; called by muse, mutect2, varscan2
- SLC2A4 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 149/490 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.065); catalogued as COSV50300327; called by muse, mutect2, varscan2
- SLC30A6 | c.711G>C p.L237F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV50871776; called by muse, mutect2, varscan2
- SLC51A | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs746289096, COSV56350759; called by muse, mutect2, varscan2
- SLC5A2 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57889915; called by muse, mutect2, varscan2
- SLC5A4 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV56668012; called by muse, mutect2, varscan2
- SLC5A8 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73310322; called by muse, mutect2, varscan2
- SLC9B2 | c.1014G>C p.K338N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV60017164; called by muse, mutect2, varscan2
- SMC5 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.288); catalogued as COSV63191391; called by muse, mutect2, varscan2
- SMCHD1 | c.2854G>C p.E952Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV55250803, COSV55266294; called by muse, mutect2, varscan2
- SMG9 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV54213349; called by muse, mutect2, varscan2
- SMPDL3A | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as COSV63755064; called by muse, mutect2, varscan2
- SNAI2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV50078589; called by muse, mutect2, varscan2
- SNAPC4 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100047032; called by muse, mutect2
- SNRK | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.09); catalogued as COSV56065506; called by muse, mutect2, varscan2
- SNX12 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99339880; called by muse, mutect2, varscan2
- SON | c.3353A>T p.Y1118F | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV51649245; called by muse, mutect2, varscan2
- SOX2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57620832; called by muse, mutect2, varscan2
- SPAST | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM004659, CM1510060, COSV59512424; called by muse, mutect2, varscan2
- SPATA16 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV63526104; called by muse, mutect2, varscan2
- SPATA32 | c.69-1G>C p.X23_splice | Splice Site (SNP) | VAF 30/118 reads (25%) | catalogued as COSV59302790; called by mutect2, varscan2
- SPATA5 | c.2330G>C p.R777T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as COSV56771055; called by muse, mutect2, varscan2
- SPO11 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV61994977; called by muse, mutect2, varscan2
- SPOCD1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV57093434; called by muse, mutect2, varscan2
- SPTBN2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs1257151945, COSV59445868; called by muse, mutect2, varscan2
- SPTBN5 | c.8815G>C p.E2939Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1043192317, COSV58015761; called by muse, mutect2, varscan2
- SRFBP1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV59581382; called by muse, mutect2, varscan2
- SRGAP3 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64529957, COSV64532370; called by muse, mutect2, varscan2
- SRL | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as COSV68422699; called by muse, mutect2, varscan2
- SRPK2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV67000708; called by muse, mutect2, varscan2
- SSBP2 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100283265; called by muse, mutect2, varscan2
- STARD6 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as rs191887491, COSV57141276; called by muse, mutect2, varscan2
- STARD8 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs937537328, COSV99366565; called by muse, mutect2, varscan2
- STAT3 | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52882874; called by muse, mutect2, varscan2
- STAT4 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.984); catalogued as COSV61827594; called by muse, mutect2, varscan2
- SULT1B1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60206410; called by muse, mutect2, varscan2
- SULT1C4 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1220815962, COSV55597040; called by muse, mutect2, varscan2
- SUN1 | c.457G>C p.D153H (on ENST00000405266 / NM_001367651.1; = p.D103H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61777268, COSV61779557; called by muse, mutect2, varscan2
- SWSAP1 | c.674C>G p.S225C (on ENST00000312423; = p.S246C on NM_175871.4) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV55799563; called by muse, mutect2, varscan2
- SYNE1 | c.19903C>A p.Q6635K (on ENST00000367255 / NM_182961.4; = p.Q6564K on NM_033071.3) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54895977; called by muse, mutect2, varscan2
- SYNE2 | c.7259C>G p.S2420C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV59938361; called by muse, mutect2, varscan2
- TAF6 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs148566323; called by muse, mutect2, varscan2
- TASOR | c.4711C>G p.Q1571E (on ENST00000355628 / NM_001365636.2; = p.Q1195E on NM_015224.3) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV58300927; called by muse, mutect2, varscan2
- TBC1D10B | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV59769688; called by muse, mutect2, varscan2
- TBC1D3L | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1219419148; called by muse, mutect2, varscan2
- TBL1Y | c.895-1G>A p.X299_splice | Splice Site (SNP) | VAF 30/52 reads (58%) | catalogued as COSV60732284; called by muse, mutect2, varscan2
- TCEA3 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71531779; called by muse, mutect2, varscan2
- TCF23 | c.466-1G>A p.X156_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV56077821; called by muse, mutect2, varscan2
- TCHH | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs1294322130, COSV64272366; called by muse, mutect2, varscan2
- TDG | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs771470191, COSV99904121; called by muse, mutect2
- TDRKH | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58617227; called by muse, mutect2, varscan2
- TEAD2 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60543367; called by muse, mutect2, varscan2
- TECTA | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50687602, COSV50689301; called by muse, mutect2, varscan2
- TENM1 | c.8172G>C p.R2724S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV64424124; called by muse, mutect2, varscan2
- TESMIN | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV99663503; called by muse, mutect2
- TEX29 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV52094165; called by muse, mutect2, varscan2
- TG | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV55063738; called by muse, mutect2, varscan2
- TG | c.8215G>C p.E2739Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.08); catalogued as COSV55063760, COSV55095316; called by muse, mutect2, varscan2
- TGFB1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99699102; called by muse, mutect2
- THEG | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100700644, COSV61072756; called by muse, mutect2, varscan2
- THSD7A | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70259501; called by muse, mutect2, varscan2
- TLDC2 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54113347; called by muse, mutect2, varscan2
- TLE4 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV54625456; called by muse, mutect2, varscan2
- TLN1 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV59203573; called by muse, mutect2, varscan2
- TMC2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV62652318; called by muse, mutect2
- TMCO3 | c.1997G>C p.R666T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV64806543, COSV64808372; called by muse, mutect2, varscan2
- TMED8 | c.761-1G>A p.X254_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53625071; called by muse, mutect2, varscan2
- TMEM115 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV99223455; called by muse, mutect2, varscan2
- TMEM131 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV51769284; called by muse, mutect2, varscan2
- TMEM132A | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV50000025; called by muse, mutect2, varscan2
- TMEM263 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV55013485, COSV55013597; called by muse, mutect2, varscan2
- TMEM38A | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1298740529, COSV51817814; called by muse, mutect2
- TMEM45B | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55653154; called by muse, mutect2, varscan2
- TMPRSS11F | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV62464201, COSV62464564; called by muse, mutect2, varscan2
- TMPRSS4 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.723); catalogued as COSV101449365; called by muse, varscan2
- TMPRSS9 | c.959C>T p.A320V (on ENST00000648592; = p.A286V on NM_182973.2) | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.299); catalogued as rs746335015, COSV60225361; called by muse, mutect2, varscan2
- TNRC6A | c.3592G>C p.E1198Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV59360236; called by muse, mutect2, varscan2
- TOM1L2 | c.897C>A p.F299L (on ENST00000379504 / NM_001350333.2; = p.F249L on NM_001033551.3) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58883810; called by muse, mutect2, varscan2
- TP53 | c.873del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV52664629, COSV52760527, COSV52774013; called by pindel, varscan2
- TP53BP1 | c.4013G>A p.R1338K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55495742, COSV99780585; called by muse, mutect2, varscan2
- TPH2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV61590278; called by muse, mutect2, varscan2
- TPK1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1191650770, COSV63636469; called by muse, mutect2, varscan2
- TPM1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51259628; called by muse, mutect2, varscan2
- TRAF3IP2 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV60674945; called by muse, mutect2, varscan2
- TRANK1 | c.8446G>A p.E2816K | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV57139346; called by muse, mutect2, varscan2
- TRERF1 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 107/429 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.101); catalogued as rs139388497; called by muse, mutect2, varscan2
- TRIM16L | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV67459032; called by muse, mutect2, varscan2
- TRIM32 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100531113, COSV57747440; called by muse, mutect2, varscan2
- TRIM68 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as COSV56167281; called by muse, mutect2, varscan2
- TRIOBP | c.5482G>T p.E1828* (on ENST00000644935 / NM_001039141.3; = p.E115* on NM_007032.5) | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100462261; called by muse, mutect2
- TRIT1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV57546927; called by muse, mutect2, varscan2
- TRMO | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs766055932, COSV63336565; called by muse, mutect2, varscan2
- TRPC4AP | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs779832508, COSV52676493, COSV52683176; called by muse, mutect2, varscan2
- TTC17 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV50005678; called by muse, mutect2, varscan2
- TTC7B | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100127255; called by muse, mutect2
- TTI1 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as COSV100989611; called by muse, mutect2, varscan2
- TTN | c.71992G>C p.E23998Q (on ENST00000591111; = p.E16574Q on NM_003319.4) | Missense Mutation (SNP) | VAF 52/226 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV59863868; called by muse, mutect2, varscan2
- TTN | c.9865C>T p.H3289Y (on ENST00000591111; = p.H3243Y on NM_003319.4) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | PolyPhen possibly damaging (0.67); catalogued as COSV100627604, COSV59863902; called by muse, mutect2, varscan2
- TTN | c.9724C>G p.L3242V (on ENST00000591111; = p.L3196V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | PolyPhen benign (0.01); catalogued as COSV59863930; called by muse, mutect2, varscan2
- TUBGCP3 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99996687; called by muse, mutect2, varscan2
- U2SURP | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749860940, COSV67529861; called by muse, mutect2, varscan2
- UBA52 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV55890688, COSV99723643; called by muse, mutect2, varscan2
- UBR4 | c.4684G>C p.D1562H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV64382104; called by muse, mutect2, varscan2
- UBXN6 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs763386494, COSV56669824; called by muse, mutect2, varscan2
- ULK3 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51510019; called by muse, mutect2, varscan2
- UNC13A | c.4215G>C p.L1405F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1568505908, COSV53187069; called by muse, mutect2, varscan2
- UNC13B | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760142420, COSV65930941; called by muse, mutect2, varscan2
- UNC79 | c.5817C>G p.I1939M (on ENST00000393151 / NM_001346218.2; = p.I1762M on NM_020818.5) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV56371905; called by muse, mutect2, varscan2
- USF3 | c.4829G>A p.R1610K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57069362; called by muse, mutect2, varscan2
- USF3 | c.1701G>A p.M567I | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57069394; called by muse, mutect2, varscan2
- USO1 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.442); catalogued as COSV53712128, COSV99362688; called by muse, mutect2, varscan2
- USP30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV57447982; called by muse, mutect2, varscan2
- USP8 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV56161835; called by muse, mutect2, varscan2
- UTP25 | c.1837C>G p.H613D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV71965709, COSV71965729; called by muse, mutect2, varscan2
- UTS2 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99276724; called by muse, mutect2
- VCAN | c.8662G>C p.E2888Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54095771; called by muse, mutect2, varscan2
- VEPH1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs558817084, COSV62875415; called by muse, mutect2, varscan2
- VGF | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1209990073, COSV50800803; called by muse, mutect2, varscan2
- VIL1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50285311; called by muse, mutect2, varscan2
- VSIG2 | c.722G>C p.R241P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV52517777, COSV52517790; called by muse, mutect2, varscan2
- WAC | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as COSV61566436; called by muse, mutect2, varscan2
- WAPL | c.1754C>G p.S585* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99556385; called by muse, mutect2
- WASF1 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as COSV100846822; called by muse, mutect2, varscan2
- WBP11 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV53761565; called by muse, mutect2, varscan2
- WDFY3 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs757583006, COSV55692194, COSV55697607; called by muse, mutect2, varscan2
- WDR11 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as COSV54784901; called by muse, mutect2, varscan2
- WDR72 | c.712-1G>C p.X238_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64741069, COSV64755086; called by muse, mutect2, varscan2
- WDR76 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV55476508; called by muse, mutect2, varscan2
- WNT10B | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV56404714; called by muse, mutect2, varscan2
- WWTR1 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62290241; called by muse, mutect2, varscan2
- XIRP2 | c.4690G>T p.E1564* (on ENST00000628543; = p.E1739* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54720325, COSV99740935; called by muse, mutect2, varscan2
- XIRP2 | c.5615C>G p.S1872C (on ENST00000628543; = p.S2047C on NM_152381.6) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs191159891, COSV54679976, COSV54712409; called by muse, mutect2, varscan2
- XRCC2 | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV63769898, COSV63770046; called by muse, mutect2, varscan2
- XRN1 | c.2123C>G p.S708* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99377627; called by muse, mutect2, varscan2
- YY2 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 211/279 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63410567, COSV63412659; called by muse, mutect2, varscan2
- ZC3H4 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53410133; called by muse, mutect2, varscan2
- ZC3HC1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV61296995; called by muse, mutect2, varscan2
- ZCCHC8 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs768861686, COSV60316870; called by muse, mutect2, varscan2
- ZDHHC1 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV99339419; called by muse, mutect2, varscan2
- ZFP36L1 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100322423, COSV60543958; called by muse, mutect2, varscan2
- ZFP36L2 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56696867; called by muse, mutect2, varscan2
- ZFP41 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV58085920, COSV58087798; called by muse, mutect2, varscan2
- ZFY | c.1922C>G p.S641* | Nonsense Mutation (SNP) | VAF 25/33 reads (76%) | catalogued as COSV99324192; called by muse, mutect2, varscan2
- ZGRF1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100005428; called by muse, mutect2, varscan2
- ZNF133 | c.574C>G p.Q192E (on ENST00000316358 / NM_001352454.2; = p.Q191E on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV60366112; called by muse, mutect2, varscan2
- ZNF143 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55178230; called by muse, mutect2, varscan2
- ZNF248 | c.1227A>T p.E409D | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV61996960; called by muse, mutect2, varscan2
- ZNF256 | c.1659G>C p.W553C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV56596052; called by muse, mutect2, varscan2
- ZNF274 | c.1033G>C p.E345Q (on ENST00000610905; = p.E240Q on NM_016324.3) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.093); catalogued as COSV58762730; called by muse, mutect2, varscan2
- ZNF277 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV62462979; called by muse, mutect2, varscan2
- ZNF283 | c.1942C>G p.H648D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs755182537, COSV61030326; called by muse, mutect2
- ZNF324B | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV60740420; called by muse, mutect2, varscan2
- ZNF35 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV56075782; called by muse, mutect2, varscan2
- ZNF442 | c.153G>C p.K51N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54420150; called by muse, mutect2, varscan2
- ZNF462 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52929102; called by muse, mutect2, varscan2
- ZNF483 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV58514389; called by muse, mutect2, varscan2
- ZNF536 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV62817522; called by muse, mutect2, varscan2
- ZNF540 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100329586, COSV57110828; called by muse, mutect2, varscan2
- ZNF546 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV61257004; called by muse, mutect2, varscan2
- ZNF583 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99382040; called by muse, mutect2, varscan2
- ZNF629 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52697165; called by muse, mutect2, varscan2
- ZNF670 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV63607487; called by muse, mutect2, varscan2
- ZNF671 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV58051519; called by muse, mutect2, varscan2
314 further variants in this file (23 protein-altering or splice-affecting, 261 silent, 30 other) are not listed here.
